EXCEPTIONAL_RESPONDERS case ER-B0GQ — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4914eb6-6939-40ad-a433-f6a7ed0a2be0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Alive.

Diagnoses (2)
1. Ductal carcinoma in situ, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,861 days); Year of diagnosis: 2004; AJCC clinical stage: Stage I; Prior malignancy: yes; Days to last follow up: 2,243 days (6.1 years); Days to best overall response: 2,243 days (6.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 2,052 days (5.6 years); Days to treatment end: 2,205 days (6.0 years).
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 2,056 days (5.6 years); Days to treatment end: 4,568 days (12.5 years).
2. Diagnosis record without a diagnosis name: Age at diagnosis: 65.5 years (23,940 days); AJCC pathologic stage: Stage II.

Follow-up (1 entry)
- Days to follow up: 2,243 days (6.1 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 2,041 days (5.6 years); Days progression-free: 2,243 days (6.1 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GQ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 2; Percent tumor nuclei: 3; Percent normal cells: 80; Percent necrosis: 10; Percent stromal cells: 8; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
